ALCHEMIST case ALCH-AEQE — Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial (ALCHEMIST-ALCH)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026).
https://portal.gdc.cancer.gov/cases/e659cf17-f6ae-45b1-a2d0-a77fc2573270

Demographics
Sex at birth: female.

Diagnoses (1)
1. Adenocarcinoma, NOS: Age at diagnosis: 77.3 years (28,248 days).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ALCH-AEQE-NB1-A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Fresh.
- Sample ALCH-AEQE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ALCH-AEQE-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 32; Percent tumor nuclei: 50; Percent normal cells: 30; Percent necrosis: 3; Percent stromal cells: 35; Percent lymphocyte infiltration: 35; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 1.
